MMRF case MMRF_2217 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/baca798a-2fc1-4b78-9c66-78a4935b336b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.8 years (22,220 days); ISS stage: III; Days to last known disease status: 905 days (2.5 years); Days to last follow up: 905 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 373 days (1.0 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 254 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 254 days; Days to treatment end: 373 days (1.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 373 days (1.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 4: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1390 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.79 mg/dL; Immunoglobulin G 3.83 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 6.92 µg/mL; Lactate Dehydrogenase 3.57 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 11.2 ×10⁹/L; Absolute Neutrophil 7.95 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 3 mmol/L; Glucose 7.48 mmol/L; C-Reactive Protein 2.86 mg/dL.
- Day 100 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.113 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 4.18 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.84 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 6.11 mmol/L.
- Day 170 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.242 mg/dL; Immunoglobulin G 4.29 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.43 µg/mL; Hemoglobin 8.43 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.79 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.4 g/dL; Glucose 6.82 mmol/L.
- Day 289 (ECOG 0): Hemoglobin 7.87 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.47 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 6 mmol/L.
- Day 373 (ECOG 0): Hemoglobin 8.12 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.89 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.2 g/dL; Glucose 6.16 mmol/L.
- Day 429: Hemoglobin 8 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 295 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.38 mmol/L; Glucose 6.27 mmol/L.
- Day 548: Hemoglobin 8.93 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.56 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 7.04 mmol/L.
- Day 604 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.813 mg/dL; Immunoglobulin G 4.43 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 9.18 mmol/L; Leukocytes 5 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 97.2 µmol/L; Total Protein 6.6 g/dL.
- Day 659 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 13.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.873 mg/dL; Hemoglobin 8.43 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 4.52 ×10⁹/L; Platelets 334 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 905: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Hemoglobin 8.68 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.84 ×10⁹/L; Platelets 274 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Total Protein 6.6 g/dL.

Other clinical attributes
- Day 4: Weight: 85 kg; Height: 177 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Kidney Cancer.

Biospecimens (2 samples)
- Sample MMRF_2217_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 4 days.
- Sample MMRF_2217_2_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 4 days.
